Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2Z, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2Z-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Addendum *

....

Clinical Diagnosis & History:

History of RLE pleomorphic sarcoma.

Specimens Submitted:

1: SP: Radical resection right thigh sarcoma, questionable high grade

DIAGNOSIS:

1. SKIN AND SOFT TISSUE, RIGHT THIGH; RADICAL RESECTION:
- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, PLEOMORPHIC AND STORIFORM TYPE.
- TUMOR SIZE: 6.3 X 5.6 X 4.5 CM.
- TUMOR ENCASES LARGE NERVE TRUNKS AND INVOLVES SKELETAL MUSCLE.
- TUMOR IS PREDOMINANTLY VIABLE WITH FOCAL TUMOR NECROSIS (<5% OF TUMOR VOLUME).
- ALL MARGINS ARE FREE OF TUMOR (MINIMAL CLEARANCE 0.2 CM FROM LATERAL AND MEDIAL MARGINS).

NOTE: THERE IS A FOCAL DENSE LYMPHOID INFILTRATE NEXT TO THE TUMOR. IMMUNOSTAINS TO FURTHER CHARACTERIZE THE INFILTRATE WILL BE PERFORMED AND REPORTED IN AN ADDENDUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled, "radical resection right thigh sarcoma ? high grade MFH stitch marks short superior long lateral ". It consists of an oriented portion of brown/red soft tissue measuring 14 x 9 x 7.5 cm, with an attached ellipse of tan grossly unremarkable skin measuring 14 x 2.5 cm. The specimen is inked: lateral - black, medial - yellow, deep

** Continued on next page **

ICD O-3

Histiocytoma, fibrous
malignant pleomorphic
8880/3

Site - thigh NOS
0496

7/23/10/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3
- blue, superior - green, and inferior - red. Sectioning reveals a well circumscribed solid bulging tan mass measuring 6.3 x 5.6 x 4.5 cm. It is present 0.2 cm from lateral and medial margins, 0.5 cm from deep margin, 1.5 cm from superior margin, 2.5 cm from inferior margin, and 2.8 cm from the skin. In the center of the mass there is a 1 cm yellow discolored area, representing < 5% of the mass volume. Also there is a 2 x 1.6 x 1.4 cm white fibrous firm area within the medial aspect of the mass, representing approximately 10% of the mass volume. Photographs are taken. Tissue is submitted to TPS. Representative sections are submitted.

Summary of sections:
SM - superior margin
IM - inferior margin
MM - medial margin
LM -lateral margin
DM - deep margin
S - skin
T tumor (yellow area in 9, white in 12-14).

Summary of Sections:
Part 1: SP: Radical resection right thigh sarcoma, questionable high grade

Block	Sect.	Site	PCs
1		DM	2
1		IM	2
1		LM	2
1		MM	2
1		S	1
1		SM	2
8		T	8

Procedures/Addenda:
Addendum
Date Ordered: Status: Signed Out
Date Complete: By:
Date Reported:

Addendum Diagnosis
1. SKIN AND SOFT TISSUE, RIGHT THIGH; RADICAL RESECTION:
-IMMUNOSTAINS SHOW THAT THE LYMPHOCYTIC INFILTRATE IS COMPOSED
PREDOMINANTLY OF CD3 POSITIVE T CELLS WITH SCATTERED CD20 POSITIVE B CELLS,
WHICH IS IN FAVOR OF A REACTIVE PROCESS.
- FINDINGS WERE REVIEWED WITH WHO AGREES.

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 3 of 3

** End of Report **

Source: NCI Genomic Data Commons file a479df3e-7640-42e3-b77d-0810120609c7 (TCGA-DX-AB2Z.7A6BA316-9BA4-4A33-B7C6-0D96CF1F4994.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).